Somatic mutation profile of tumor specimen CDDP-ABL4-TTP1-A (aliquot CDDP-ABL4-TTP1-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABL4, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 44 years.
Specimen CDDP-ABL4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13e73fab-9a1c-4d09-b9e4-ee90d460fd94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABL4-NB1-A (Blood Derived Normal), aliquot CDDP-ABL4-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3da4887d-6d74-4484-90af-0cbf1e0ee003

The open-access MAF lists 621 somatic variants for this specimen: 430 protein-altering or splice-affecting, 116 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 360, Silent 116, Intron 34, Nonsense Mutation 29, Frame Shift Del 14, RNA 14, 5'UTR 12, Splice Site 12, Splice Region 7, 3'Flank 5, 5'Flank 5, 3'UTR 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 210/356 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.812A>T p.E271V | Missense Mutation (SNP) | VAF 207/539 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM942136, COSV52661418, COSV52925998, COSV53589174; called by muse, mutect2, varscan2
- ABT1 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as rs150105438, COSV51291480; called by muse, mutect2, varscan2
- AC100868.1 | c.1367C>A p.P456Q | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV51844815, COSV99226469; called by muse, mutect2, varscan2
- ACADL | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs1226951841; called by muse, mutect2, varscan2
- ADAM18 | c.2015C>G p.S672C | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs1320012914, COSV55854489; called by muse, mutect2, varscan2
- ADAMTS16 | c.1633C>A p.R545S | Missense Mutation (SNP) | VAF 108/285 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.628); catalogued as COSV56980020; called by muse, mutect2, varscan2
- AGTR1 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs1400159105, COSV62557114; called by muse, mutect2, varscan2
- ALK | c.1669C>A p.R557S | Missense Mutation (SNP) | VAF 73/300 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.06); catalogued as COSV66561092, COSV66594696; called by muse, mutect2, varscan2
- ATAD5 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as COSV58977882; called by muse, mutect2, varscan2
- ATP1A2 | c.2935C>A p.P979T | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100767821; called by muse, mutect2, varscan2
- BAZ2B | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58595960; called by muse, mutect2, varscan2
- BCHE | c.1383G>T p.W461C | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012532; called by muse, mutect2, varscan2
- BOC | c.352G>T p.V118L | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV56349747; called by muse, mutect2, varscan2
- BTAF1 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 64/227 reads (28%) | catalogued as COSV99795802; called by muse, mutect2, varscan2
- C8A | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs772455324, COSV63485646; called by muse, mutect2, varscan2
- CACNA1E | c.6865G>T p.G2289W (on ENST00000367573 / NM_001205293.3; = p.G2246W on NM_000721.4) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62409794; called by muse, mutect2, varscan2
- CACNA2D3 | c.1994G>T p.R665L | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV55541845; called by muse, mutect2, varscan2
- CALN1 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 53/267 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.046); catalogued as rs759101499; called by muse, mutect2, varscan2
- CAPRIN1 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as COSV58221812, COSV58222137; called by muse, mutect2, varscan2
- CCDC102B | c.1429G>C p.D477H | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV100104903; called by muse, mutect2, varscan2
- CETN3 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51618407; called by muse, mutect2, varscan2
- CFAP47 | c.8674G>A p.A2892T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as COSV66218625; called by muse, mutect2, varscan2
- CHGA | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); catalogued as rs1278173503; called by muse, mutect2, varscan2
- CLIP2 | c.746G>T p.C249F | Missense Mutation (SNP) | VAF 72/313 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56280465; called by muse, mutect2, varscan2
- CNBD1 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as rs370736889, COSV72976790; called by muse, mutect2, varscan2
- CNR2 | c.879G>C p.M293I | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV65692404; called by muse, mutect2, varscan2
- COL3A1 | c.4377C>A p.D1459E | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.278); catalogued as COSV58595658; called by muse, varscan2
- COL9A1 | c.2581G>T p.G861C | Missense Mutation (SNP) | VAF 109/365 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57882206; called by muse, mutect2, varscan2
- CRISPLD1 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV51546794; called by muse, mutect2, varscan2
- CTSC | c.830A>G p.N277S | Missense Mutation (SNP) | VAF 148/465 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs1308728982; called by muse, mutect2, varscan2
- CYP2B6 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 157/386 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs760667555, COSV57845374; called by muse, mutect2, varscan2
- DCAF4L2 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 118/505 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs772779530; called by muse, mutect2, varscan2
- DCDC1 | c.3232C>A p.P1078T (on ENST00000597505 / NM_001367979.1; = p.P185T on NM_020869.3) | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs760520245; called by muse, mutect2, varscan2
- DDI1 | c.793A>G p.M265V | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs376710370; called by muse, mutect2, varscan2
- DDX5 | c.831G>T p.M277I | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56749401; called by muse, mutect2, varscan2
- DHX35 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755282012, COSV52672386; called by muse, mutect2, varscan2
- DISP1 | c.1438G>T p.G480C | Missense Mutation (SNP) | VAF 126/378 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52659933; called by muse, mutect2, varscan2
- DPEP1 | c.445A>T p.S149C | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99878312; called by muse, mutect2, varscan2
- DSG4 | c.2569T>C p.S857P | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV57389850; called by muse, mutect2, varscan2
- EFCAB1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.136); catalogued as COSV50619159; called by muse, mutect2, varscan2
- EFHD1 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1320046181; called by muse, mutect2, varscan2
- EPHB1 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.804); catalogued as rs748807854, COSV67665061; called by muse, mutect2, varscan2
- ESRRG | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV63173879; called by muse, varscan2
- ETNK1 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV56884502; called by muse, varscan2
- ETV6 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 141/249 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56767059; called by muse, mutect2, varscan2
- F10 | c.1152C>A p.Y384* | Nonsense Mutation (SNP) | VAF 91/423 reads (22%) | catalogued as rs371569721; called by muse, mutect2, varscan2
- FAM135B | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50537682; called by muse, mutect2, varscan2
- FAT3 | c.919del p.D307Ifs*3 | Frame Shift Del (DEL) | VAF 31/241 reads (13%) | catalogued as COSV53142296; called by mutect2, pindel, varscan2
- FBXO11 | c.628A>G p.M210V (on ENST00000403359 / NM_001190274.2; = p.M126V on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1037057182, COSV57019274; called by muse, mutect2, varscan2
- FHL5 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58739365; called by muse, mutect2, varscan2
- FSIP2 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); catalogued as rs753918887; called by muse, mutect2, varscan2
- GALNT17 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61145704; called by muse, mutect2, varscan2
- GBP5 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 56/389 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1557501570, COSV58593914; called by mutect2, varscan2
- GLT1D1 | c.957C>A p.Y319* (on ENST00000442111 / NM_001366889.1; = p.Y239* on NM_144669.3) | Nonsense Mutation (SNP) | VAF 27/198 reads (14%) | catalogued as COSV55884128; called by muse, mutect2, varscan2
- GORASP2 | c.1243A>T p.T415S | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1477774455; called by muse, mutect2, varscan2
- GPC6 | c.1329G>T p.Q443H | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1277692372; called by muse, mutect2, varscan2
- GPR15 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1559660454; called by muse, mutect2, varscan2
- GRIA2 | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs778623018, COSV99643923; called by muse, mutect2, varscan2
- HELZ | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV100698612; called by muse, mutect2
- HEPH | c.1174G>T p.D392Y (on ENST00000343002; = p.D125Y on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57959914; called by muse, mutect2, varscan2
- HJURP | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV100982555; called by muse, mutect2, varscan2
- HMCN1 | c.8047G>C p.E2683Q | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54909988; called by muse, mutect2
- HS3ST4 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.346); catalogued as COSV58800491; called by muse, varscan2
- HSF1 | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.7); catalogued as COSV60048838; called by muse, mutect2, varscan2
- HTR7 | c.1414G>A p.E472K (on ENST00000336152 / NM_019859.4; = p.R439K on NM_000872.5) | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1411508570; called by muse, mutect2, varscan2
- IDI1 | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs773066093; called by muse, mutect2, varscan2
- IGKV6D-41 | c.188C>A p.A63D | Missense Mutation (SNP) | VAF 77/375 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs772221263; called by muse, mutect2, varscan2
- ITCH | c.996G>T p.W332C (on ENST00000262650 / NM_001257137.3; = p.W291C on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/332 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52936052; called by muse, mutect2, varscan2
- ITGA8 | c.2216C>A p.S739Y | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as COSV100959906, COSV65226089; called by muse, mutect2, varscan2
- KIF5C | c.2741C>T p.A914V | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1355720697; called by muse, mutect2, varscan2
- MAGEC3 | c.61T>C p.W21R | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV53575785; called by muse, mutect2, varscan2
- MALSU1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1192095817; called by muse, mutect2, varscan2
- MARCKS | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs1312246618; called by muse, mutect2, varscan2
- MCM4 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 112/260 reads (43%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.476); catalogued as rs966403056, COSV50621294; called by muse, mutect2, varscan2
- MDGA2 | c.736G>T p.V246F | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs1052252244; called by muse, mutect2, varscan2
- MROH9 | c.617-1G>T p.X206_splice | Splice Site (SNP) | VAF 40/153 reads (26%) | catalogued as rs761520213, COSV63010976; called by muse, mutect2, varscan2
- MYO15B | c.7432A>G p.T2478A | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1261128440; called by muse, mutect2, varscan2
- MYO7B | c.3124C>T p.R1042W | Missense Mutation (SNP) | VAF 20/303 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs200719203; called by muse, mutect2
- NAGLU | c.1095G>T p.Q365H | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754764611; called by muse, mutect2, varscan2
- NAV2 | c.179C>A p.S60* | Nonsense Mutation (SNP) | VAF 21/149 reads (14%) | catalogued as COSV100587101; called by muse, mutect2, varscan2
- NOTCH3 | c.5570G>A p.R1857Q | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200883235; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPAS2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV59559358; called by muse, mutect2, varscan2
- NPY5R | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as rs1211818515, COSV58453547; called by muse, mutect2, varscan2
- NRAP | c.4520C>A p.A1507E (on ENST00000359988 / NM_001322945.2; = p.A1472E on NM_006175.4) | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV63488266, COSV63494182; called by muse, mutect2, varscan2
- NSG2 | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV57456943; called by muse, mutect2, varscan2
- OMA1 | c.764A>T p.E255V | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV62255416; called by muse, mutect2, varscan2
- OR13C2 | c.8G>T p.W3L | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV73377800; called by muse, varscan2
- OR4D10 | c.827C>A p.T276N | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs1443803454, COSV101597026; called by muse, mutect2
- OR4K2 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768493157, COSV53848239; called by muse, mutect2, varscan2
- OR52L1 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1362399187; called by muse, mutect2, varscan2
- OR5I1 | c.414G>T p.M138I | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV56888051; called by muse, mutect2, varscan2
- OR7C2 | c.391C>A p.H131N | Missense Mutation (SNP) | VAF 99/223 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as rs1021078546; called by muse, mutect2, varscan2
- PACS1 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as rs753938016, COSV57696314; called by muse, mutect2, varscan2
- PANX3 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs766598167, COSV52513815, COSV99421153; called by muse, mutect2, varscan2
- PCDH15 | c.4199G>T p.R1400I | Missense Mutation (SNP) | VAF 36/389 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100221551; called by muse, mutect2
- PDZRN4 | c.475G>T p.G159* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as COSV68414157; called by muse, mutect2, varscan2
- PIEZO2 | c.910T>A p.Y304N | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs751565062; called by muse, varscan2
- PIK3C2B | c.4384C>T p.P1462S | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs537055085; called by muse, mutect2, varscan2
- PIK3C2G | c.4214A>T p.H1405L (on ENST00000676171; = p.H1364L on NM_004570.5) | Missense Mutation (SNP) | VAF 122/219 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs758057388; called by muse, mutect2, varscan2
- PLOD3 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 98/508 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs750298633, COSV56182725; called by muse, mutect2, varscan2
- PLXNA3 | c.1888G>A p.G630S | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs781946606; called by muse, mutect2, varscan2
- PNMA1 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1166243327; called by muse, mutect2, varscan2
- POLR1A | c.221G>A p.C74Y | Missense Mutation (SNP) | VAF 74/289 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99808277; called by muse, mutect2, varscan2
- PSD2 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs949109972, COSV51202775; called by muse, mutect2, varscan2
- PTPRS | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV53611032; called by muse, mutect2, varscan2
- RBFOX1 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1435075625; called by muse, mutect2, varscan2
- REG1A | c.338G>C p.W113S | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52071771; called by muse, mutect2, varscan2
- RIF1 | c.4708G>A p.G1570R | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1466334732; called by mutect2, varscan2
- ROBO2 | c.2986C>G p.P996A | Missense Mutation (SNP) | VAF 79/398 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59908077; called by muse, mutect2, varscan2
- RYR3 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as COSV66808523; called by muse, mutect2, varscan2
- SERPINB3 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1489212565; called by muse, mutect2, varscan2
- SLC8A1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60487770, COSV60493960; called by muse, mutect2, varscan2
- SNAPC4 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 105/286 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs141436235; called by muse, mutect2, varscan2
- SPANXN2 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 135/386 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65129244; called by muse, varscan2
- TBC1D12 | c.827C>A p.T276K | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.187); catalogued as rs1336279543; called by muse, mutect2, varscan2
- TESK1 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 97/238 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1335185912; called by muse, mutect2, varscan2
- TEX15 | c.6847G>A p.E2283K (on ENST00000256246; = p.E2666K on NM_001350162.2) | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs148557222; called by muse, mutect2, varscan2
- THSD7A | c.374G>T p.R125I | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV101448961; called by muse, mutect2, varscan2
- TMPO | c.1846G>T p.G616W | Missense Mutation (SNP) | VAF 111/254 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.954); catalogued as rs1371958325; called by muse, mutect2, varscan2
- TRABD2A | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs935802556, COSV59104998; called by muse, mutect2, varscan2
- TRMT6 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766405213, COSV52542704; called by muse, mutect2, varscan2
- TRPV5 | c.1455G>A p.M485I | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.942); catalogued as COSV99520802; called by muse, mutect2
- TTC5 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs763037053; called by muse, mutect2, varscan2
- TTN | c.88463C>A p.S29488Y (on ENST00000591111; = p.S22064Y on NM_003319.4) | Missense Mutation (SNP) | VAF 63/253 reads (25%) | PolyPhen possibly damaging (0.667); catalogued as COSV100619216, COSV100625269; called by muse, mutect2, varscan2
- TUBA3E | c.74G>A p.C25Y | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1248075942; called by muse, mutect2, varscan2
- TYR | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs61759520; called by muse, mutect2, varscan2
- UBE2V2 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV72879220; called by muse, mutect2, varscan2
- UBQLNL | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV66494793; called by muse, mutect2, varscan2
- WDFY4 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1056070442; called by muse, mutect2, varscan2
- WNT10A | c.605G>T p.S202I | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV51462590; called by muse, mutect2, varscan2
- ZBP1 | c.621G>T p.Q207H | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100474149; called by muse, mutect2, varscan2
- ZDBF2 | c.2191C>T p.L731F | Missense Mutation (SNP) | VAF 21/255 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.843); catalogued as COSV65627570; called by muse, mutect2
- ZNF222 | c.1226G>C p.R409P | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); catalogued as COSV99496341; called by muse, mutect2, varscan2
- ZNF521 | c.3312C>A p.S1104R | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as COSV64123018; called by muse, mutect2, varscan2
- ZNF648 | c.1517G>T p.C506F | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100374590; called by muse, mutect2, varscan2
- ZNF669 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs773240977; called by muse, mutect2, varscan2
- ZNF716 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 101/304 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.031); catalogued as COSV70779824; called by muse, mutect2, varscan2
- ZNF716 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV70782356; called by muse, mutect2, varscan2
- ZNF843 | c.607G>T p.G203W | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV59848680; called by muse, mutect2, varscan2
- ABCA13 | c.7134G>T p.K2378N | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ABCC12 | c.2489C>A p.P830H | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- ABCG2 | c.1813T>A p.Y605N | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ABLIM3 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 86/229 reads (38%) | called by muse, mutect2, varscan2
- AC024598.1 | c.961del p.Q321Kfs*12 | Frame Shift Del (DEL) | VAF 24/164 reads (15%) | called by mutect2, pindel, varscan2
- ACBD7 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 26/274 reads (9%) | called by muse, mutect2, varscan2
- ACSM2B | c.1293C>G p.D431E | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM7 | c.1996G>T p.V666F | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ADAMTS10 | c.2960C>A p.P987H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTS20 | c.4743G>T p.K1581N | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ADGRG4 | c.7348G>A p.E2450K | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRL3 | c.1118A>G p.Y373C (on ENST00000506720 / NM_001322402.2; = p.Y305C on NM_015236.6) | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFF1 | c.889A>G p.M297V | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- AGBL4 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- AHNAK | c.15206C>A p.A5069D | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AHNAK2 | c.9423C>A p.S3141R | Missense Mutation (SNP) | VAF 139/341 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- AIPL1 | c.544C>A p.H182N | Missense Mutation (SNP) | VAF 109/300 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AKR1B15 | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKR1B15 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ALOX5AP | c.173A>G p.Q58R | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AMBP | c.260+2T>C p.X87_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- AMPD2 | c.665A>T p.K222M | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- AP1AR | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- APBB1IP | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- APP | c.101T>A p.I34N | Missense Mutation (SNP) | VAF 85/339 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ARHGAP17 | c.2549G>T p.S850I (on ENST00000289968 / NM_001006634.3; = p.S772I on NM_018054.6) | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.548); called by muse, varscan2
- ARHGEF26 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARMC2 | c.1450T>A p.Y484N | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ATP2B2 | c.1976G>A p.R659H (on ENST00000352432; = p.R625H on NM_001683.5) | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATXN7L1 | c.255G>C p.M85I | Missense Mutation (SNP) | VAF 187/358 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- B3GALNT1 | c.741A>T p.R247S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BCL11B | c.478T>A p.S160T | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- BCL9L | c.3056G>T p.G1019V | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- BOD1L1 | c.6379G>C p.D2127H | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- BPIFB6 | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- C1orf127 | c.2168C>G p.S723* | Nonsense Mutation (SNP) | VAF 28/183 reads (15%) | called by muse, mutect2, varscan2
- C1orf141 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- C4orf54 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CACNA1B | c.6139G>T p.A2047S | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CADM2 | c.451A>C p.S151R (on ENST00000407528 / NM_001167674.2; = p.S153R on NM_153184.4) | Missense Mutation (SNP) | VAF 111/257 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBY2 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CCDC15 | c.2214+1G>T p.X738_splice | Splice Site (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- CCDC8 | c.1498C>A p.P500T | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CCDC86 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CCKAR | c.879del p.N294Tfs*12 | Frame Shift Del (DEL) | VAF 80/343 reads (23%) | called by mutect2, pindel, varscan2
- CCNT2 | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 87/377 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CD248 | c.192del p.E65Rfs*150 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | called by mutect2, pindel, varscan2
- CDC42BPA | c.4749G>T p.M1583I (on ENST00000334218 / NM_001366019.2; = p.M1570I on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CDH10 | c.1646C>T p.T549I | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CDHR2 | c.2258G>T p.W753L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CDK16 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CEP135 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- CEP350 | c.6995_6996del p.R2332Tfs*9 | Frame Shift Del (DEL) | VAF 32/232 reads (14%) | called by pindel, varscan2
- CFAP47 | c.1815-2A>T p.X605_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- CHD5 | c.1669G>T p.G557C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CHD6 | c.7252G>T p.G2418W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHD8 | c.5128-4C>T | Splice Region (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- CHGA | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CLTCL1 | c.3852G>T p.E1284D | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- CNNM3 | c.850G>T p.G284W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- COL14A1 | c.2902G>T p.G968W | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL24A1 | c.1627C>A p.P543T | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- COL6A3 | c.7159T>A p.C2387S | Missense Mutation (SNP) | VAF 126/537 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- COL9A1 | c.2581+1G>T p.X861_splice | Splice Site (SNP) | VAF 107/362 reads (30%) | called by muse, mutect2, varscan2
- COQ3 | c.1040A>T p.K347M | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CPEB1 | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 32/176 reads (18%) | called by muse, mutect2, varscan2
- CRISP2 | c.230A>G p.K77R | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CROCC2 | c.3074G>T p.R1025L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CSF3 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD1 | c.4487+1del p.X1496_splice (on ENST00000520002; = p.X1495_splice on NM_033225.6) | Splice Site (DEL) | VAF 40/145 reads (28%) | called by mutect2, pindel, varscan2
- CSMD3 | c.9306G>T p.W3102C (on ENST00000297405 / NM_001363185.1; = p.W2933C on NM_052900.3) | Missense Mutation (SNP) | VAF 86/390 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CSMD3 | c.2200T>C p.S734P (on ENST00000297405 / NM_001363185.1; = p.S630P on NM_052900.3) | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTNND2 | c.950T>C p.I317T | Missense Mutation (SNP) | VAF 87/506 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DENND2D | c.269A>C p.Q90P | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- DKKL1 | c.227T>C p.M76T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.08); called by mutect2, varscan2
- DMXL1 | c.8417A>T p.D2806V | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.9967A>T p.T3323S | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- DNAH9 | c.5761T>A p.F1921I | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- DNAI4 | c.1602G>C p.Q534H | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC1 | c.199T>C p.Y67H | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, varscan2
- DNAJC6 | c.2173G>T p.G725* | Nonsense Mutation (SNP) | VAF 32/147 reads (22%) | called by muse, mutect2, varscan2
- DPP6 | c.1055C>G p.P352R (on ENST00000377770 / NM_001364500.2; = p.P290R on NM_001936.5) | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPP6 | c.2326G>C p.V776L (on ENST00000377770 / NM_001364500.2; = p.V714L on NM_001936.5) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DSG2 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- DSPP | c.871C>A p.H291N | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYSF | c.2692G>T p.G898C | Missense Mutation (SNP) | VAF 76/322 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFCAB5 | c.841G>T p.V281L | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- EML3 | c.2008A>G p.R670G | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ENAM | c.1219G>T p.G407W | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- EPHA7 | c.2227G>T p.A743S | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ESRRG | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- F2R | c.302T>A p.L101Q | Missense Mutation (SNP) | VAF 92/213 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAAP20 | c.235A>C p.T79P | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FAAP20 | c.234C>A p.F78L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FAM184B | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.58); called by muse, mutect2
- FAM217B | c.667A>T p.R223* | Nonsense Mutation (SNP) | VAF 66/206 reads (32%) | called by muse, mutect2, varscan2
- FAM237A | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- FAT3 | c.13624_13625del p.A4542Qfs*48 | Frame Shift Del (DEL) | VAF 59/337 reads (18%) | called by mutect2, pindel, varscan2
- FAT4 | c.6926C>T p.T2309I | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBN2 | c.4463C>T p.S1488F | Missense Mutation (SNP) | VAF 130/332 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, varscan2
- FCGBP | c.6220G>C p.A2074P | Missense Mutation (SNP) | VAF 65/502 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FHOD3 | c.1135A>T p.S379C | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLVCR2 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- FOXC1 | c.1239G>T p.Q413H | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- FUT2 | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 42/283 reads (15%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- GABRA3 | c.1144-2A>G p.X382_splice | Splice Site (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- GAD2 | c.617C>A p.T206N | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- GBP5 | c.665T>A p.L222Q | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- GFRA1 | c.1262A>T p.E421V | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GIMAP8 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 191/502 reads (38%) | called by muse, mutect2, varscan2
- GJB7 | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- GRIK1 | c.1333G>T p.A445S | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2
- GRIN2B | c.2070C>G p.S690R | Missense Mutation (SNP) | VAF 190/322 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRK3 | c.292_306del p.E98_L102del | In Frame Del (DEL) | VAF 23/174 reads (13%) | called by mutect2, pindel, varscan2
- GSTT2B | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- GTF2A1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GTF3C2 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HAS2 | c.628-2A>G p.X210_splice | Splice Site (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- HKDC1 | c.907G>T p.G303W | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXA3 | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.017); called by muse, mutect2
- HOXD9 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HS6ST2 | c.1295G>A p.G432D | Missense Mutation (SNP) | VAF 76/230 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HYDIN | c.12698C>G p.T4233S | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ICE1 | c.3431G>A p.R1144K | Missense Mutation (SNP) | VAF 93/396 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- IFNGR2 | c.1009_*4del | Nonstop Mutation (DEL) | VAF 40/225 reads (18%) | called by mutect2, pindel, varscan2
- IGHG3 | c.1125+7G>C | Splice Region (SNP) | VAF 40/358 reads (11%) | called by muse, mutect2, varscan2
- IL12RB2 | c.1561C>A p.P521T | Missense Mutation (SNP) | VAF 94/425 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IL36G | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- INMT-MINDY4 | c.425G>C p.*142Sext*6 | Nonstop Mutation (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- INPPL1 | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ITGB2 | c.1543C>T p.Q515* (on ENST00000302347; = p.Q491* on NM_000211.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 66/293 reads (23%) | called by muse, mutect2, varscan2
- ITIH6 | c.1310T>A p.L437Q | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KDM4D | c.362dup p.L121Ffs*12 | Frame Shift Ins (INS) | VAF 62/244 reads (25%) | called by pindel, varscan2
- KDM4D | c.363_364del p.E122Afs*10 | Frame Shift Del (DEL) | VAF 98/282 reads (35%) | called by mutect2, varscan2*
- KEAP1 | c.1530A>T p.A510= | Splice Region (SNP) | VAF 58/132 reads (44%) | called by muse, mutect2, varscan2
- KIAA1549 | c.653A>C p.Q218P | Missense Mutation (SNP) | VAF 122/402 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF17 | c.923T>C p.M308T | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIR2DL3 | c.183C>G p.H61Q | Missense Mutation (SNP) | VAF 108/356 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- KISS1 | c.275G>C p.R92P | Missense Mutation (SNP) | VAF 124/349 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KLK4 | c.13G>T p.G5* | Nonsense Mutation (SNP) | VAF 109/301 reads (36%) | called by muse, mutect2, varscan2
- KNDC1 | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- KNL1 | c.3748_3754del p.V1250Tfs*32 (on ENST00000346991 / NM_170589.5; = p.V1224Tfs*32 on NM_144508.5) | Frame Shift Del (DEL) | VAF 55/250 reads (22%) | called by mutect2, pindel, varscan2
- KRBA1 | c.1673G>A p.R558K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- KRTAP1-1 | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 25/696 reads (4%) | called by muse, mutect2
- KTN1 | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LAMB4 | c.4623G>T p.R1541S | Missense Mutation (SNP) | VAF 155/375 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- LAMB4 | c.989G>T p.R330I | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- LANCL1 | c.198A>T p.A66= | Splice Region (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- LDHA | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LILRB5 | c.1597C>A p.Q533K (on ENST00000449561 / NM_001081442.3; = p.Q532K on NM_006840.5) | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- LRP1B | c.9002C>A p.P3001H | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- LRP1B | c.820T>G p.W274G | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LRP3 | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRC41 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LTBP2 | c.2670G>C p.E890D | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP3K5 | c.2065G>A p.G689S | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP4K1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MAPK12 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); called by muse, mutect2
- MDGA2 | c.2593+7G>T | Splice Region (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- MKX | c.754G>T p.G252* | Nonsense Mutation (SNP) | VAF 71/245 reads (29%) | called by muse, mutect2, varscan2
- MMP3 | c.857C>G p.T286R | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MS4A8 | c.222C>A p.A74= | Splice Region (SNP) | VAF 8/40 reads (20%) | called by muse, varscan2
- MSGN1 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- MUC17 | c.6538A>T p.T2180S | Missense Mutation (SNP) | VAF 92/217 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MYO3A | c.3275-1G>T p.X1092_splice | Splice Site (SNP) | VAF 63/243 reads (26%) | called by muse, mutect2, varscan2
- MYO9B | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYT1L | c.2901C>A p.Y967* | Nonsense Mutation (SNP) | VAF 38/144 reads (26%) | called by muse, mutect2, varscan2
- NALCN | c.3661C>A p.L1221M | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- NCAM1 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 94/276 reads (34%) | called by muse, mutect2, varscan2
- NCKAP5 | c.3653G>C p.S1218T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NDRG1 | c.549G>T p.W183C | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NDRG1 | c.548G>A p.W183* | Nonsense Mutation (SNP) | VAF 35/162 reads (22%) | called by muse, mutect2, varscan2
- NDST3 | c.1661C>A p.P554Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NEB | c.4932del p.T1645Pfs*19 | Frame Shift Del (DEL) | VAF 69/257 reads (27%) | called by mutect2, pindel, varscan2
- NLGN4X | c.1172C>A p.T391K | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- NLRP14 | c.2495G>C p.C832S | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NPC1L1 | c.1572C>G p.Y524* | Nonsense Mutation (SNP) | VAF 96/285 reads (34%) | called by muse, mutect2, varscan2
- NRAP | c.4088T>C p.M1363T (on ENST00000359988 / NM_001322945.2; = p.M1328T on NM_006175.4) | Missense Mutation (SNP) | VAF 94/325 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- NRCAM | c.1184T>G p.L395* (on ENST00000379028 / NM_001371124.1; = p.L389* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 33/160 reads (21%) | called by muse, varscan2
- NRDE2 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 38/203 reads (19%) | called by muse, mutect2, varscan2
- NTRK2 | c.53dup p.C19Lfs*43 | Frame Shift Ins (INS) | VAF 49/266 reads (18%) | called by mutect2, pindel, varscan2
- OPCML | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- OR10R2 | c.924_926del p.M308_V309delinsI | In Frame Del (DEL) | VAF 21/86 reads (24%) | called by mutect2, pindel, varscan2
- OR10W1 | c.756C>A p.C252* | Nonsense Mutation (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
- OR2D2 | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- OR2T10 | c.115G>T p.V39L | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5T3 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR6F1 | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- OR8D4 | c.383G>T p.S128I | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OTX1 | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCBP3 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PCDH11X | c.1565T>A p.L522Q | Missense Mutation (SNP) | VAF 54/289 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH15 | c.3128C>A p.P1043H | Missense Mutation (SNP) | VAF 25/293 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); called by muse, mutect2
- PCDH17 | c.1294C>A p.R432S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB9 | c.1813C>A p.Q605K | Missense Mutation (SNP) | VAF 175/504 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- PCOLCE | c.319C>G p.R107G | Missense Mutation (SNP) | VAF 87/530 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- PDE4DIP | c.2564G>T p.R855L | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PDHA2 | c.240C>A p.Y80* | Nonsense Mutation (SNP) | VAF 39/203 reads (19%) | called by muse, mutect2, varscan2
- PDHA2 | c.1132G>T p.A378S | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PDZRN4 | c.2217C>A p.Y739* (on ENST00000402685 / NM_001164595.2; = p.Y481* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 57/270 reads (21%) | called by muse, mutect2, varscan2
- PHF20L1 | c.1564G>T p.A522S | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.098); called by mutect2, varscan2
- PIP4K2B | c.195G>T p.M65I | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- PIWIL2 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, varscan2
- POLK | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- POU2F3 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PPP1R3A | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- PRAMEF15 | c.69A>C p.Q23H | Missense Mutation (SNP) | VAF 94/798 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, varscan2
- PRDM9 | c.2143A>T p.T715S | Missense Mutation (SNP) | VAF 236/922 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.024); called by muse, varscan2
- PRKD1 | c.629C>A p.T210N | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PRR35 | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- PRSS12 | c.2191_2194dup p.L732* | Nonsense Mutation (INS) | VAF 65/358 reads (18%) | called by mutect2, pindel, varscan2
- PSG5 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PTCH2 | c.2420G>T p.R807L | Missense Mutation (SNP) | VAF 85/387 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRA | c.1781_1785+2del p.X594_splice | Splice Site (DEL) | VAF 27/70 reads (39%) | called by mutect2, pindel, varscan2
- PTPRS | c.713G>C p.R238P | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- RAB3IL1 | c.955del p.D319Tfs*46 | Frame Shift Del (DEL) | VAF 68/226 reads (30%) | called by mutect2, pindel, varscan2
- RAPGEF6 | c.3910A>T p.T1304S | Missense Mutation (SNP) | VAF 118/310 reads (38%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBP3 | c.3204G>T p.W1068C | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RC3H2 | c.2115G>T p.M705I | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RCC1L | c.385A>C p.T129P | Missense Mutation (SNP) | VAF 25/370 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2
- RELN | c.6725G>T p.R2242M | Missense Mutation (SNP) | VAF 217/470 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- RELN | c.6724A>T p.R2242W | Missense Mutation (SNP) | VAF 216/472 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RELN | c.3649A>T p.I1217F | Missense Mutation (SNP) | VAF 107/636 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- RIOK2 | c.667G>T p.G223W | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASE9 | c.488A>T p.Y163F | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- RNF227 | c.300G>C p.L100F | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ROBO1 | c.2883G>T p.R961S | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- SCN10A | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SDC1 | c.26G>T p.W9L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SEMA4D | c.677G>C p.G226A | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SEMA4F | c.1577A>G p.Q526R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA5A | c.1946T>A p.L649Q | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- SERPINA7 | c.816del p.K273Rfs*17 | Frame Shift Del (DEL) | VAF 88/279 reads (32%) | called by mutect2, pindel, varscan2
- SETBP1 | c.2698del p.D900Tfs*61 | Frame Shift Del (DEL) | VAF 73/249 reads (29%) | called by mutect2, pindel, varscan2
- SGIP1 | c.1654C>A p.L552I | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SHROOM3 | c.3173G>C p.R1058P | Missense Mutation (SNP) | VAF 91/479 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SHROOM4 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIPA1L1 | c.3519A>G p.E1173= | Splice Region (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
- SLC25A25 | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.086); called by muse, mutect2
- SLC6A2 | c.176G>T p.W59L | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK2 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SON | c.4529G>T p.G1510V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SORCS1 | c.1850G>T p.G617V | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORCS1 | c.1071C>A p.N357K | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SRBD1 | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 93/307 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- SRRM1 | c.2466_2468dup p.D822_K823insN | In Frame Ins (INS) | VAF 29/192 reads (15%) | called by mutect2, pindel, varscan2
- STARD13 | c.211G>T p.G71W | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUSD5 | c.856T>A p.S286T | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- TAF2 | c.3315G>T p.L1105F | Missense Mutation (SNP) | VAF 106/493 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TBCK | c.793G>T p.D265Y (on ENST00000273980 / NM_001163436.4; = p.D202Y on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TCF20 | c.2218G>T p.G740W | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- TDRD15 | c.2193T>A p.F731L | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX13C | c.1904C>A p.P635Q | Missense Mutation (SNP) | VAF 130/421 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); called by muse, varscan2
- TEX44 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 130/453 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TLK2 | c.2204T>C p.L735P (on ENST00000326270 / NM_001284333.2; = p.L713P on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TMEM201 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TMEM215 | c.319A>C p.S107R | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- TMEM63C | c.1102C>A p.Q368K | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMPRSS7 | c.2336T>A p.M779K (on ENST00000452346; = p.M653K on NM_001042575.2) | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TOM1 | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- TPK1 | c.592A>T p.T198S | Missense Mutation (SNP) | VAF 93/249 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TPO | c.2241C>A p.S747R | Missense Mutation (SNP) | VAF 94/336 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, varscan2
- TPO | c.2265C>A p.H755Q | Missense Mutation (SNP) | VAF 78/378 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.177); called by muse, varscan2
- TRAV24 | c.269C>A p.T90N | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- TRAV39 | c.112dup p.T38Nfs*47 | Frame Shift Ins (INS) | VAF 75/253 reads (30%) | called by mutect2, pindel, varscan2
- TRIM42 | c.2018C>A p.T673K | Missense Mutation (SNP) | VAF 104/266 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM55 | c.986-2A>T p.X329_splice | Splice Site (SNP) | VAF 54/154 reads (35%) | called by muse, varscan2
- TRIM64C | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 39/257 reads (15%) | called by muse, mutect2, varscan2
- TRPV2 | c.580T>A p.C194S | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TSHZ2 | c.2139del p.L713Ffs*30 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- TSHZ3 | c.2194C>A p.H732N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TTLL4 | c.1916G>T p.G639V | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- TTN | c.47587T>A p.Y15863N (on ENST00000591111; = p.Y8439N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTYH1 | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- TUBA4B | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBN1 | c.1199G>C p.R400P | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- UGT2B15 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USH2A | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- VAV1 | c.828-2A>C p.X276_splice | Splice Site (SNP) | VAF 84/187 reads (45%) | called by muse, mutect2, varscan2
- VCAM1 | c.1087G>T p.G363W | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZEB1 | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 81/601 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZFP30 | c.488G>T p.C163F | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZMAT1 | c.735G>T p.M245I | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ZNF229 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZNF469 | c.11325del p.S3776Afs*2 (on ENST00000437464; = p.S3804Afs*2 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 168/520 reads (32%) | called by mutect2, pindel, varscan2
- ZNF536 | c.3469A>G p.T1157A | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF557 | c.1108G>C p.E370Q (on ENST00000414706 / NM_001044388.2; = p.E377Q on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2
- ZNF629 | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSCAN4 | c.728C>A p.S243* | Nonsense Mutation (SNP) | VAF 102/206 reads (50%) | called by muse, varscan2
- A3GALT2 | c.558G>A p.G186= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs1264222634; called by muse, mutect2
- ADAM10 | c.2064G>T p.L688= | Silent (SNP) | VAF 64/265 reads (24%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.2961C>A p.P987= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99547499; called by muse, mutect2, varscan2
- ADGRG4 | c.3021C>A p.T1007= | Silent (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- AGL | c.4143T>C p.F1381= | Silent (SNP) | VAF 46/324 reads (14%) | called by muse, varscan2
- ANXA9 | c.483G>T p.V161= | Silent (SNP) | VAF 25/142 reads (18%) | called by muse, mutect2, varscan2
- ASIC2 | c.648G>T p.G216= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- ATP6V1B2 | c.201G>A p.R67= | Silent (SNP) | VAF 63/149 reads (42%) | catalogued as rs953134655; called by muse, mutect2, varscan2
- BRINP1 | c.1734C>A p.P578= | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as rs552169514, COSV56300211; called by muse, mutect2, varscan2
- C2CD6 | c.786C>T p.S262= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as rs1238154478; called by muse, mutect2, varscan2
- CADPS2 | c.3597A>T p.I1199= | Silent (SNP) | VAF 99/189 reads (52%) | called by muse, mutect2, varscan2
- CCRL2 | c.519G>A p.Q173= | Silent (SNP) | VAF 30/142 reads (21%) | called by muse, mutect2, varscan2
- CD177 | c.1017C>T p.S339= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as rs1304124340; called by muse, mutect2, varscan2
- CD37 | c.705G>A p.Q235= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as COSV60545164; called by muse, mutect2, varscan2
- CHRNA5 | c.489G>T p.P163= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2
- CPS1 | c.1503A>T p.P501= | Silent (SNP) | VAF 56/191 reads (29%) | called by muse, mutect2, varscan2
- CPXM2 | c.195C>A p.P65= | Silent (SNP) | VAF 28/105 reads (27%) | called by muse, mutect2, varscan2
- CYP2A13 | c.1179T>C p.P393= | Silent (SNP) | VAF 69/178 reads (39%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.864G>T p.L288= | Silent (SNP) | VAF 36/107 reads (34%) | called by muse, mutect2, varscan2
- DDX60L | c.3357G>T p.V1119= | Silent (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- DES | c.1360C>A p.R454= | Silent (SNP) | VAF 58/245 reads (24%) | catalogued as CM071700, COSV64660545; called by muse, mutect2, varscan2
- DOCK5 | c.3789G>T p.T1263= | Silent (SNP) | VAF 70/204 reads (34%) | catalogued as rs541260988; called by muse, mutect2, varscan2
- DPP8 | c.165G>C p.R55= (on ENST00000341861 / NM_001320875.2; = p.R39= on NM_017743.6) | Silent (SNP) | VAF 35/238 reads (15%) | called by muse, mutect2, varscan2
- DRAXIN | c.261C>T p.A87= | Silent (SNP) | VAF 40/161 reads (25%) | called by muse, mutect2, varscan2
- DTL | c.1353C>T p.A451= | Silent (SNP) | VAF 50/137 reads (36%) | called by muse, mutect2, varscan2
- FAM209A | c.81G>A p.Q27= | Silent (SNP) | VAF 43/303 reads (14%) | catalogued as rs1483183707; called by muse, mutect2, varscan2
- FAM214A | c.2514A>G p.L838= | Silent (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- FBXO22 | c.420C>G p.P140= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV57619290; called by muse, mutect2, varscan2
- FBXO46 | c.1266A>T p.P422= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV58347993; called by muse, mutect2, varscan2
- FOXG1 | c.942G>A p.L314= | Silent (SNP) | VAF 125/445 reads (28%) | called by muse, mutect2, varscan2
- FRG2C | c.630G>T p.L210= | Silent (SNP) | VAF 23/698 reads (3%) | called by muse, mutect2
- GAD2 | c.618C>T p.T206= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as rs1025999960; called by muse, mutect2, varscan2
- GALP | c.33C>A p.L11= | Silent (SNP) | VAF 57/157 reads (36%) | called by muse, mutect2, varscan2
- GPR15 | c.588C>A p.S196= | Silent (SNP) | VAF 50/144 reads (35%) | called by muse, mutect2, varscan2
- GRIN3B | c.1935C>A p.L645= | Silent (SNP) | VAF 22/129 reads (17%) | called by muse, mutect2, varscan2
- H2AC1 | c.210G>T p.A70= | Silent (SNP) | VAF 58/140 reads (41%) | catalogued as COSV51238038; called by muse, mutect2, varscan2
- HBB | c.96G>T p.L32= | Silent (SNP) | VAF 57/378 reads (15%) | catalogued as rs778841729; called by muse, mutect2, varscan2
- HERC1 | c.13146G>C p.V4382= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs747429095; called by muse, mutect2, varscan2
- HKDC1 | c.906G>T p.L302= | Silent (SNP) | VAF 52/150 reads (35%) | called by muse, varscan2
- HNRNPDL | c.324G>A p.A108= | Silent (SNP) | VAF 43/226 reads (19%) | catalogued as rs1001839263; called by muse, mutect2, varscan2
- IFT140 | c.765C>T p.S255= | Silent (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- IGFBP1 | c.471C>A p.T157= | Silent (SNP) | VAF 27/177 reads (15%) | catalogued as COSV99298805; called by muse, mutect2, varscan2
- IGKV1-27 | c.97C>T p.L33= | Silent (SNP) | VAF 49/441 reads (11%) | catalogued as rs1355562352; called by muse, mutect2, varscan2
- ITIH6 | c.1311G>T p.L437= | Silent (SNP) | VAF 42/97 reads (43%) | called by muse, mutect2, varscan2
- KANK3 | c.1647C>T p.S549= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs1236550839; called by muse, mutect2
- KCNA1 | c.567C>T p.L189= | Silent (SNP) | VAF 56/146 reads (38%) | called by muse, mutect2, varscan2
- KCND1 | c.1524G>T p.P508= | Silent (SNP) | VAF 64/160 reads (40%) | called by muse, mutect2, varscan2
- KIF25 | c.612G>A p.V204= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs772947616; called by muse, mutect2, varscan2
- KRT25 | c.627C>T p.T209= | Silent (SNP) | VAF 38/213 reads (18%) | called by muse, mutect2, varscan2
- KRTAP13-2 | c.312C>A p.S104= | Silent (SNP) | VAF 41/243 reads (17%) | called by muse, mutect2, varscan2
- LRP1B | c.883C>A p.R295= | Silent (SNP) | VAF 30/134 reads (22%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1719C>A p.A573= | Silent (SNP) | VAF 31/277 reads (11%) | called by muse, mutect2, varscan2
- MAPK7 | c.1290C>T p.A430= | Silent (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- MARCO | c.489C>A p.G163= | Silent (SNP) | VAF 45/191 reads (24%) | catalogued as COSV59052667; called by muse, mutect2, varscan2
- MFAP3L | c.432C>T p.F144= | Silent (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- MRE11 | c.1158G>C p.V386= | Silent (SNP) | VAF 46/314 reads (15%) | catalogued as rs925169397; called by muse, mutect2, varscan2
- MUC16 | c.22293G>T p.V7431= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV67462550; called by muse, mutect2, varscan2
- MUC4 | c.9678C>T p.S3226= | Silent (SNP) | VAF 41/187 reads (22%) | called by muse, mutect2, varscan2
- MYO19 | c.351C>T p.V117= | Silent (SNP) | VAF 6/105 reads (6%) | called by muse, mutect2
- MYOF | c.5064A>G p.Q1688= | Silent (SNP) | VAF 25/204 reads (12%) | called by muse, mutect2, varscan2
- N4BP2 | c.2817G>A p.K939= | Silent (SNP) | VAF 31/213 reads (15%) | catalogued as COSV54704558; called by muse, mutect2, varscan2
- NKX2-5 | c.756C>T p.A252= | Silent (SNP) | VAF 84/190 reads (44%) | catalogued as rs1561619213; called by muse, mutect2, varscan2
- NLRP3 | c.2856G>T p.T952= | Silent (SNP) | VAF 50/365 reads (14%) | called by muse, mutect2, varscan2
- NTNG1 | c.1032C>T p.L344= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99640231; called by muse, mutect2, varscan2
- NTRK1 | c.2034C>A p.T678= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV62329089; called by muse, mutect2, varscan2
- OR11H2 | c.172C>A p.R58= (on ENST00000556246; = p.R69= on NM_001197287.1) | Silent (SNP) | VAF 42/716 reads (6%) | catalogued as rs747808926; called by muse, mutect2
- OR4C15 | c.447C>A p.G149= (on ENST00000314644; = p.G95= on NM_001001920.2) | Silent (SNP) | VAF 91/294 reads (31%) | called by muse, mutect2, varscan2
- OR4S2 | c.597C>A p.A199= | Silent (SNP) | VAF 54/167 reads (32%) | called by muse, mutect2, varscan2
- OR5B12 | c.39G>T p.V13= | Silent (SNP) | VAF 15/71 reads (21%) | called by muse, varscan2
- OR6F1 | c.786C>A p.T262= | Silent (SNP) | VAF 46/227 reads (20%) | called by muse, mutect2, varscan2
- ORAI2 | c.465G>T p.V155= | Silent (SNP) | VAF 81/455 reads (18%) | catalogued as COSV62689380; called by muse, mutect2, varscan2
- PAN2 | c.2556G>A p.L852= (on ENST00000425394 / NM_001127460.3; = p.L848= on NM_014871.5) | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV57753935; called by muse, mutect2, varscan2
- PCDHGA11 | c.2196G>T p.G732= | Silent (SNP) | VAF 33/100 reads (33%) | called by muse, mutect2, varscan2
- PCDHGA9 | c.2235G>T p.G745= | Silent (SNP) | VAF 65/150 reads (43%) | catalogued as rs372851700; called by muse, mutect2, varscan2
- PCK1 | c.1578C>G p.L526= | Silent (SNP) | VAF 54/348 reads (16%) | called by muse, mutect2, varscan2
- PI4KA | c.288G>T p.V96= | Silent (SNP) | VAF 24/133 reads (18%) | called by muse, mutect2, varscan2
- PLG | c.864T>C p.A288= | Silent (SNP) | VAF 79/234 reads (34%) | catalogued as COSV51984044; called by muse, mutect2, varscan2
- PLOD3 | c.1947G>T p.V649= | Silent (SNP) | VAF 62/253 reads (25%) | called by muse, mutect2, varscan2
- POU6F2 | c.816C>A p.P272= | Silent (SNP) | VAF 59/144 reads (41%) | catalogued as COSV68874722; called by muse, mutect2, varscan2
- PRDM13 | c.720G>T p.P240= | Silent (SNP) | VAF 41/104 reads (39%) | called by muse, mutect2, varscan2
- PTPRD | c.426G>C p.T142= | Silent (SNP) | VAF 86/186 reads (46%) | catalogued as COSV61931924, COSV61980517; called by muse, mutect2, varscan2
- PUM3 | c.813G>T p.L271= | Silent (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
- PVRIG | c.915C>T p.P305= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as rs373802845; called by muse, mutect2, varscan2
- RDH13 | c.474G>T p.L158= (on ENST00000415061 / NM_001145971.2; = p.L87= on NM_138412.4) | Silent (SNP) | VAF 79/177 reads (45%) | called by muse, mutect2, varscan2
- RP1 | c.4812T>C p.Y1604= | Silent (SNP) | VAF 47/226 reads (21%) | catalogued as rs1248796772; called by muse, mutect2, varscan2
- RPLP2 | c.102G>T p.A34= | Silent (SNP) | VAF 41/128 reads (32%) | called by muse, mutect2, varscan2
- SCN10A | c.555G>A p.L185= | Silent (SNP) | VAF 48/127 reads (38%) | catalogued as COSV101479332; called by muse, mutect2, varscan2
- SCN5A | c.382C>T p.L128= | Silent (SNP) | VAF 27/141 reads (19%) | called by muse, mutect2, varscan2
- SELE | c.474C>A p.I158= | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- SH3TC1 | c.675G>A p.T225= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as rs555239011, COSV55288738; called by muse, mutect2, varscan2
- SHANK3 | c.2566C>T p.L856= | Silent (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- SLC22A25 | c.1155T>C p.F385= | Silent (SNP) | VAF 80/266 reads (30%) | catalogued as rs573689151; called by muse, varscan2
- SLC4A3 | c.570G>T p.S190= | Silent (SNP) | VAF 47/174 reads (27%) | catalogued as rs1239067058, COSV56092410, COSV56096283; called by muse, mutect2, varscan2
- SMARCA2 | c.936G>T p.P312= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs747096590, COSV61810113; called by muse, mutect2, varscan2
- ST14 | c.379C>T p.L127= | Silent (SNP) | VAF 108/469 reads (23%) | called by muse, mutect2, varscan2
- STARD9 | c.2253G>T p.L751= | Silent (SNP) | VAF 45/180 reads (25%) | called by muse, mutect2, varscan2
- STEAP3 | c.1122G>A p.L374= | Silent (SNP) | VAF 69/336 reads (21%) | catalogued as rs768724830; called by muse, mutect2, varscan2
- TCF20 | c.2061A>T p.A687= | Silent (SNP) | VAF 59/162 reads (36%) | called by muse, mutect2, varscan2
- TDRD5 | c.624G>A p.P208= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as rs1453107837, COSV54239564; called by muse, mutect2
- THEMIS2 | c.921C>A p.G307= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- TLCD3B | c.591G>T p.L197= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.1239T>C p.T413= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs1357215326; called by muse, mutect2, varscan2
- TRAJ44 | c.60G>T p.T20= | Silent (SNP) | VAF 40/208 reads (19%) | catalogued as rs1271757049; called by muse, mutect2, varscan2
- TRAV24 | c.270C>A p.T90= | Silent (SNP) | VAF 52/171 reads (30%) | called by muse, mutect2, varscan2
- TRAV8-6 | c.171A>G p.Q57= | Silent (SNP) | VAF 69/263 reads (26%) | called by muse, mutect2, varscan2
- TRBV3-1 | c.39C>A p.L13= | Silent (SNP) | VAF 34/222 reads (15%) | called by muse, varscan2
- TRIM64C | c.1098C>A p.T366= | Silent (SNP) | VAF 81/398 reads (20%) | called by muse, mutect2, varscan2
- TRIM71 | c.249G>T p.A83= | Silent (SNP) | VAF 64/118 reads (54%) | called by muse, mutect2, varscan2
- TRPM4 | c.2268G>A p.P756= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as rs752448175; called by muse, mutect2, varscan2
- TTN | c.54093C>G p.V18031= (on ENST00000591111; = p.V10607= on NM_003319.4) | Silent (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- TYW1 | c.1632C>T p.I544= | Silent (SNP) | VAF 26/329 reads (8%) | called by muse, mutect2
- UNC80 | c.981C>A p.A327= | Silent (SNP) | VAF 32/120 reads (27%) | called by muse, varscan2
- UPP2 | c.318C>A p.T106= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV50047061, COSV99134708; called by muse, mutect2, varscan2
- USP11 | c.654C>A p.T218= (on ENST00000218348; = p.T175= on NM_001371072.1) | Silent (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- USP37 | c.1611T>C p.S537= | Silent (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- VAMP8 | c.174C>T p.F58= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV55705592, COSV55705699; called by muse, mutect2
- ABTB1 | c.-42C>T | 5'UTR (SNP) | VAF 38/200 reads (19%) | catalogued as rs200194975, COSV99229578; called by muse, mutect2, varscan2
- AC079154.1 | n.1016del | RNA (DEL) | VAF 45/280 reads (16%) | called by mutect2, pindel, varscan2
- ADAMTSL4 | c.-85+947C>A | Intron (SNP) | VAF 52/282 reads (18%) | called by muse, mutect2, varscan2
- ADGRB3 | c.2481-680G>C | Intron (SNP) | VAF 40/95 reads (42%) | catalogued as rs1348932498; called by muse, mutect2, varscan2
- ANO6 | c.345+33A>C | Intron (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- ANXA8 | chr10:47484130 A>G | 5'Flank (SNP) | VAF 38/465 reads (8%) | catalogued as rs1456783558; called by muse, mutect2
- ATPAF1 | chr1:46633777 C>A | 3'Flank (SNP) | VAF 27/136 reads (20%) | called by muse, mutect2, varscan2
- BNC2 | c.2639+5626T>G | Intron (SNP) | VAF 66/149 reads (44%) | called by muse, mutect2, varscan2
- C11orf80 | chr11:66843450 G>T | 3'Flank (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2
- C8orf34 | c.1106-14797G>C | Intron (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- C8orf74 | c.242-10465C>A | Intron (SNP) | VAF 46/132 reads (35%) | called by muse, mutect2, varscan2
- CDH19 | c.1336+2314G>T | Intron (SNP) | VAF 17/43 reads (40%) | catalogued as COSV50960105; called by muse, mutect2, varscan2
- CDH9 | c.999+19C>T | Intron (SNP) | VAF 95/196 reads (48%) | called by muse, mutect2, varscan2
- CFHR1 | c.59-21A>T | Intron (SNP) | VAF 48/191 reads (25%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*408C>T | 3'UTR (SNP) | VAF 67/196 reads (34%) | called by muse, mutect2, varscan2
- CLUHP11 | n.182C>A | RNA (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- CROCC2 | c.4557+573G>C | Intron (SNP) | VAF 22/187 reads (12%) | called by muse, mutect2, varscan2
- CSGALNACT1 | c.*91C>A | 3'UTR (SNP) | VAF 52/131 reads (40%) | catalogued as COSV100175393; called by muse, mutect2, varscan2
- CTNND2 | c.2638-1060C>T | Intron (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- DES | c.-29C>G | 5'UTR (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- DHRS2 | c.421-1494C>G | Intron (SNP) | VAF 50/156 reads (32%) | called by muse, mutect2, varscan2
- EPHB2 | c.62-6214G>T | Intron (SNP) | VAF 33/176 reads (19%) | catalogued as rs558511651; called by muse, mutect2, varscan2
- ETNK1 | c.416+279C>T | Intron (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- GRIK4 | c.-277G>T | 5'UTR (SNP) | VAF 38/89 reads (43%) | called by muse, mutect2, varscan2
- GUSBP10 | n.119C>A | RNA (SNP) | VAF 34/215 reads (16%) | called by muse, mutect2, varscan2
- GVINP1 | n.4639C>T | RNA (SNP) | VAF 46/153 reads (30%) | called by muse, mutect2, varscan2
- HCN4 | c.-30C>A | 5'UTR (SNP) | VAF 36/152 reads (24%) | called by muse, mutect2
- HDGF | c.716+57G>T | Intron (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1114G>T | RNA (SNP) | VAF 71/304 reads (23%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.2117G>A | RNA (SNP) | VAF 9/168 reads (5%) | catalogued as rs570144428; called by muse, mutect2
- ING1 | chr13:110714263 G>T | 5'Flank (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- KAZALD1 | c.*1509C>A | 3'UTR (SNP) | VAF 31/135 reads (23%) | called by muse, mutect2, varscan2
- LDB2 | c.236-78422C>A | Intron (SNP) | VAF 32/210 reads (15%) | called by muse, mutect2, varscan2
- LINC02693 | n.685+4222G>T | Intron (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- LONRF3 | c.1060-2337G>T | Intron (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- LTA4H | c.-4T>A | 5'UTR (SNP) | VAF 69/151 reads (46%) | called by muse, mutect2, varscan2
- LVRN | c.2757-660A>T | Intron (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- MIR600 | n.64_71del | RNA (DEL) | VAF 15/37 reads (41%) | called by mutect2, pindel*, varscan2*
- MORF4 | n.651G>A | RNA (SNP) | VAF 46/266 reads (17%) | called by muse, mutect2, varscan2
- MPRIP | c.2164-4817G>T | Intron (SNP) | VAF 45/214 reads (21%) | called by muse, mutect2, varscan2
- MPV17 | c.71-4072C>T | Intron (SNP) | VAF 26/103 reads (25%) | catalogued as rs925726868; called by muse, mutect2, varscan2
- MYB | c.-45G>T | 5'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- MYO19 | c.894+696A>G | Intron (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2, varscan2
- NBPF11 | c.-124G>T | 5'UTR (SNP) | VAF 32/323 reads (10%) | called by muse, varscan2
- NCAN | c.3409+41del | Intron (DEL) | VAF 54/154 reads (35%) | called by mutect2, pindel, varscan2
- NFASC | c.-112G>C | 5'UTR (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- NGEF | c.-75+128C>A | Intron (SNP) | VAF 36/119 reads (30%) | called by muse, mutect2, varscan2
- NRG1 | chr8:31640234 G>A | 5'Flank (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- OFCC1 | n.1569G>A | RNA (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- OTOF | c.2215-119del | Intron (DEL) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- PAX4 | c.*95C>A | 3'UTR (SNP) | VAF 75/273 reads (27%) | catalogued as COSV100490400; called by muse, mutect2, varscan2
- PAX8 | c.-13C>A | 5'UTR (SNP) | VAF 99/409 reads (24%) | catalogued as rs754271156, COSV54511832; called by muse, mutect2, varscan2
- PCDHGC3 | c.2430+152_2430+153dup | Intron (INS) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
- PLPBP | chr8:37784218 C>A | 3'Flank (SNP) | VAF 69/128 reads (54%) | called by muse, mutect2, varscan2
- PRKAG2 | c.754+312G>C | Intron (SNP) | VAF 76/220 reads (35%) | called by muse, mutect2, varscan2
- PROS1 | c.*41A>G | 3'UTR (SNP) | VAF 72/270 reads (27%) | called by muse, mutect2, varscan2
- PTF1A | c.-53C>T | 5'UTR (SNP) | VAF 14/181 reads (8%) | catalogued as rs1194250279; called by muse, mutect2
- RBPJ | c.194+3812T>A | Intron (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | n.113del | RNA (DEL) | VAF 28/83 reads (34%) | called by mutect2, pindel, varscan2
- SATB2 | c.1173+102G>T | Intron (SNP) | VAF 19/95 reads (20%) | called by muse, mutect2, varscan2
- SDF2 | c.151+532C>T | Intron (SNP) | VAF 13/111 reads (12%) | catalogued as rs772966136; called by muse, mutect2, varscan2
- SHCBP1L | chr1:182953209 C>T | 5'Flank (SNP) | VAF 43/123 reads (35%) | called by muse, mutect2, varscan2
- SIM2 | c.258+33C>A | Intron (SNP) | VAF 18/115 reads (16%) | catalogued as COSV51770743; called by muse, mutect2, varscan2
- SLC13A1 | c.661-1198G>T | Intron (SNP) | VAF 27/81 reads (33%) | catalogued as rs931223938; called by muse, mutect2, varscan2
- SNORD115-23 | n.18C>A | RNA (SNP) | VAF 7/62 reads (11%) | catalogued as rs1208743832; called by muse, mutect2, varscan2
- SNORD116-22 | chr15:25091984 C>A | 3'Flank (SNP) | VAF 19/100 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.13637G>T | RNA (SNP) | VAF 49/134 reads (37%) | called by muse, mutect2, varscan2
- TASP1 | c.282+8616C>T | Intron (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- TRIM67 | chr1:231219930 C>A | 3'Flank (SNP) | VAF 53/204 reads (26%) | called by muse, mutect2, varscan2
- TRPM1 | c.-3G>C | 5'UTR (SNP) | VAF 26/136 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.10360+2184del | Intron (DEL) | VAF 34/206 reads (17%) | called by mutect2, pindel, varscan2
- UBBP4 | n.587G>C | RNA (SNP) | VAF 26/645 reads (4%) | catalogued as rs1362289502; called by muse, mutect2
- XIST | n.10717C>A | RNA (SNP) | VAF 82/227 reads (36%) | called by muse, mutect2, varscan2
- ZKSCAN8 | chr6:28136939 A>T | 5'Flank (SNP) | VAF 70/195 reads (36%) | called by muse, mutect2, varscan2
- ZNF12 | c.-561C>T | 5'UTR (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2, varscan2
